Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5789, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5789-01A (Primary Tumor).

TCGA-CH-5789

Final diagnosis

Prostate tissue with infiltration of a moderately differentiated adenocarcinoma with perineural carcinoma infiltration. Gleason 3+3=6). Blue labeled preparation margin tumor-free. No extraprostatic carcinoma growth. No identifiable invasion of the vessels.

Diagnosis

1. Poorly differentiated, max. 2.5 cm, acinar adenocarcinoma of the prostate in both lobes with perineural growth along major nerves and small focal infiltration of the periprostatic right dorsolateral fatty connective tissue in the middle section of the prostate and close to the base. Tumor-free seminal vesicles and seminal ducts.
2. Three tumor-free, partly scarred and lipomatous lymph nodes. No malignancy.
3. A tumor-free, partly scarred lymph node. No malignancy.

Remark

Carcinoma infiltrates are found in the dorsal and dorsolateral peripheral zone of both prostate lobes with right-sided predominance. No identifiable invasion of the vessels. The preparation margin labeled green and blue is carcinoma-free.

In summary, the tumor classification to date is as follows: pT3a, pN0 (0/4), Gleason 3+4 = 7, Gleason 4: 40%, G3, L0, V0.

Source: NCI Genomic Data Commons file 01a850d5-15d9-4d30-9a0b-1a3db9cc246d (TCGA-CH-5789.50E47B92-4C6A-4FCA-8D01-0B4ABC61BD0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).